Somatic mutation profile of tumor specimen ALCH-B1TP-TTP1-A (aliquot ALCH-B1TP-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1TP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.5 years (22,815 days).
Specimen ALCH-B1TP-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4be82c41-57c4-4a49-bc4c-30c9c0970e17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1TP-NB1-A (Blood Derived Normal), aliquot ALCH-B1TP-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fb12744-010c-428a-9e01-6476b4e963e9

The open-access MAF lists 67 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 12, Intron 5, RNA 4, In Frame Del 3, Frame Shift Del 3, Nonsense Mutation 3, 3'UTR 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2240_2257del p.L747_P753delinsS | In Frame Del (DEL) | VAF 74/636 reads (12%) | hotspot (GDC flag); catalogued as rs121913438, COSV51767961; ClinVar: drug response; called by mutect2, pindel
- PIK3CA | c.316G>C p.G106R | Missense Mutation (SNP) | VAF 10/45 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519931, COSV55878215, COSV55881107, COSV55917331; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 18/151 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- BCAR1 | c.2031G>C p.K677N | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99367599; called by muse, mutect2
- DOCK2 | c.1772G>T p.G591V | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV99909750; called by muse, mutect2
- IFNA4 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 17/166 reads (10%) | catalogued as COSV70179728; called by muse, mutect2, varscan2
- ITIH5 | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.106); catalogued as COSV99904389; called by muse, mutect2, varscan2
- KCNH8 | c.2143G>C p.E715Q | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.544); catalogued as COSV60475341; called by muse, mutect2
- KMT2A | c.6841G>A p.D2281N | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as rs1447874882; called by muse, mutect2, varscan2
- LRRC3 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs760082832; called by muse, mutect2, varscan2
- MORF4L1 | c.799A>T p.M267L (on ENST00000331268 / NM_206839.2; = p.M228L on NM_006791.4) | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV58704618; called by muse, mutect2
- MYH11 | c.5371G>C p.E1791Q | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs368269107; called by muse, mutect2, varscan2
- MYO3A | c.270A>C p.K90N | Missense Mutation (SNP) | VAF 22/319 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV56319836; called by muse, mutect2
- OR3A2 | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 32/592 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68695150; called by muse, mutect2
- POLD1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as rs1060501813; called by muse, mutect2
- SCIN | c.1149G>C p.Q383H (on ENST00000297029 / NM_001112706.3; = p.Q136H on NM_033128.3) | Missense Mutation (SNP) | VAF 24/569 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV51698489, COSV99764939; called by muse, mutect2
- SIDT2 | c.1285C>T p.L429F | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs763300070; called by muse, mutect2
- SLC4A9 | c.1849C>T p.R617C (on ENST00000507527 / NM_001258428.2; = p.R593C on NM_031467.3) | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs769781263, COSV50218642; called by muse, mutect2
- TP53BP1 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.829); catalogued as rs1364542419; called by muse, mutect2, varscan2
- ZNF687 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV60682033; called by muse, mutect2, varscan2
- ANKRD18A | c.2027del p.F676Sfs*7 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- ATM | c.8935G>A p.E2979K | Missense Mutation (SNP) | VAF 20/347 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2
- CLNK | c.1028_1045del p.E343_L348del | In Frame Del (DEL) | VAF 48/456 reads (11%) | called by mutect2, pindel
- COL22A1 | c.2318G>A p.R773K | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.092); called by muse, mutect2
- DUSP11 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.048); called by muse, mutect2
- GABRA1 | c.691C>A p.Q231K | Missense Mutation (SNP) | VAF 38/474 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.113); called by muse, mutect2
- ITGA6 | c.3064G>T p.A1022S (on ENST00000442250; = p.A983S on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/570 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KDM7A | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- KIF16B | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 14/384 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); called by muse, mutect2
- LIFR | c.335_337del p.I112del | In Frame Del (DEL) | VAF 16/129 reads (12%) | called by mutect2, pindel, varscan2
- MTRR | c.907G>A p.V303M (on ENST00000264668; = p.V276M on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/1002 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- NONO | c.1249G>T p.A417S | Missense Mutation (SNP) | VAF 14/409 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.011); called by muse, mutect2
- OR14A16 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- PLS1 | c.1281C>G p.I427M | Missense Mutation (SNP) | VAF 13/209 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2
- PTPN13 | c.1134G>T p.L378F | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.009); called by muse, mutect2
- PTTG1 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 19/450 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- RNF187 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 14/374 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- RPS5 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SRPX2 | c.1305del p.T436Pfs*14 | Frame Shift Del (DEL) | VAF 56/581 reads (10%) | called by mutect2, pindel, varscan2
- TNFRSF21 | c.472A>G p.K158E | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- TUBB8 | c.1276C>T p.Q426* | Nonsense Mutation (SNP) | VAF 18/134 reads (13%) | called by muse, mutect2, varscan2
- ZNF534 | c.1054T>C p.S352P (on ENST00000332323 / NM_001143939.3; = p.S339P on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2
- ZNF92 | c.981_996del p.L328* (on ENST00000328747 / NM_152626.4; = p.L259* on NM_007139.4) | Frame Shift Del (DEL) | VAF 26/248 reads (10%) | called by mutect2, pindel, varscan2
- ANO5 | c.1833A>G p.T611= | Silent (SNP) | VAF 51/426 reads (12%) | called by muse, mutect2, varscan2
- BRD8 | c.2931C>T p.T977= | Silent (SNP) | VAF 18/380 reads (5%) | catalogued as rs1287825297; called by muse, mutect2
- ECE1 | c.213G>A p.V71= | Silent (SNP) | VAF 11/229 reads (5%) | called by muse, mutect2
- IGHA2 | c.690C>T p.N230= | Silent (SNP) | VAF 21/175 reads (12%) | catalogued as rs782272025; called by muse, mutect2, varscan2
- LRRN1 | c.951G>A p.L317= | Silent (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- MEIS1 | c.306C>T p.R102= | Silent (SNP) | VAF 26/229 reads (11%) | catalogued as rs1293032464, COSV55483311; called by muse, mutect2, varscan2
- SCG3 | c.453T>C p.I151= | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- SELENOP | c.459C>T p.F153= | Silent (SNP) | VAF 24/258 reads (9%) | catalogued as rs867134037, COSV62793337; called by muse, mutect2
- SLC6A3 | c.1146G>T p.V382= | Silent (SNP) | VAF 32/482 reads (7%) | catalogued as rs780093604; called by muse, mutect2
- SNRNP200 | c.4356G>T p.V1452= | Silent (SNP) | VAF 56/470 reads (12%) | catalogued as COSV100108148; called by muse, mutect2, varscan2
- SRRM4 | c.1242C>T p.P414= | Silent (SNP) | VAF 14/281 reads (5%) | catalogued as COSV57410680; called by muse, mutect2
- TTC14 | c.1233G>A p.L411= | Silent (SNP) | VAF 21/139 reads (15%) | called by muse, mutect2, varscan2
- ARHGEF3 | c.-71C>T | 5'UTR (SNP) | VAF 22/192 reads (11%) | catalogued as rs1269739648; called by muse, mutect2, varscan2
- CD300LD | chr17:74592321 T>A | 5'Flank (SNP) | VAF 30/222 reads (14%) | called by muse, mutect2, varscan2
- DPPA3P2 | n.329C>T | RNA (SNP) | VAF 38/536 reads (7%) | called by muse, mutect2
- EPS15 | c.561+2509A>G | Intron (SNP) | VAF 18/424 reads (4%) | catalogued as rs903125548; called by muse, mutect2
- GLTPP1 | n.291G>A | RNA (SNP) | VAF 16/190 reads (8%) | called by muse, mutect2
- MIR1185-2 | n.78C>T | RNA (SNP) | VAF 7/67 reads (10%) | catalogued as rs573712078; called by muse, mutect2, varscan2
- NACA | c.70+3804T>C | Intron (SNP) | VAF 41/257 reads (16%) | catalogued as rs780028625; called by muse, mutect2, varscan2
- RUNX1 | c.724+164A>G | Intron (SNP) | VAF 26/230 reads (11%) | called by muse, varscan2
- SCNN1A | c.1361-494G>A | Intron (SNP) | VAF 3/34 reads (9%) | catalogued as rs918017416; called by muse, mutect2
- SLC7A5P1 | n.291C>T | RNA (SNP) | VAF 10/246 reads (4%) | called by muse, mutect2
- UGT1A6 | c.862-12118C>T | Intron (SNP) | VAF 25/190 reads (13%) | catalogued as rs1392909464; called by muse, mutect2, varscan2
- XIRP2 | c.*1132C>T | 3'UTR (SNP) | VAF 9/149 reads (6%) | catalogued as COSV54739467; called by muse, mutect2
